TCGA case TCGA-RW-A68F — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: Michigan University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/813375ef-b895-4c7c-9e98-55a00f98da95

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.9 years (18,974 days); Year of diagnosis: 2010; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,354 days (3.7 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Glomus tumor, NOS: ICD-O-3 morphology code: 8711/0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Classification of tumor: Prior primary; Age at diagnosis: 33.6 years (12,278 days); Days to diagnosis: -6,696 days (-18.3 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -6,696 days (-18.3 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -6,696 days (-18.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS.
3. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Classification of tumor: Prior primary; Age at diagnosis: 48.7 years (17,786 days); Days to diagnosis: -1,188 days (-3.3 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,188 days (-3.3 years); Treatment anatomic sites: Thyroid.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -619 days (-1.7 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.
4. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 50.2 years (18,336 days); Days to diagnosis: -638 days (-1.7 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -638 days (-1.7 years); Treatment anatomic sites: Adrenal.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 457 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 1,354 days (3.7 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RW-A68F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-RW-A68F-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RW-A68F-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RW-A68F-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: right adrenal; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Glomus tumor; Other malignancy histological type: Glomus Tumor.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: Papillary Thyroid Carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: total thyroidectomy.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy histological type: Pheochromocytoma.
- Other malignancy form 3, Surgery: Other malignancy surgery type: Right adrenalectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,354 days; disease-specific survival: no event (censored), 1,354 days; disease-free interval: no event (censored), 1,354 days; progression-free interval: no event (censored), 1,354 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RW-A68F-01A-11D-A35C-01): tumor purity 0.93, ploidy 2.01, whole-genome doublings 0.
